MMRF case MMRF_1583 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/606ab4e0-a03e-45f8-9773-82a27decda9e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 49.6 years (18,117 days); ISS stage: I; Days to last known disease status: 1,290 days (3.5 years); Days to last follow up: 1,290 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 67 days; Days to treatment end: 67 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days; Days to treatment end: 262 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 261 days; Days to treatment end: 261 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 262 days; Days to treatment end: 262 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 263 days; Days to treatment end: 263 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 378 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 195 mg/dL; Immunoglobulin G 4.24 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.78 mmol/L; Albumin 50 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 91 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.232 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.013 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.51 µg/mL; Lactate Dehydrogenase 8.57 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 4.62 mmol/L.
- Day 189 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.318 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 265 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.709 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.449 mg/dL; Immunoglobulin G 8.59 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.17 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 353 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.068 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.29 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.04 g/L; Lactate Dehydrogenase 8.7 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 444 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.781 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 8.35 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 8.7 ×10⁹/L; Platelets 336 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 534 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.765 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.674 mg/dL; Immunoglobulin G 7.86 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 630 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.962 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.756 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.73 mmol/L.
- Day 728 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.753 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.649 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 820 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.767 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.643 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 911 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.655 mg/dL; Immunoglobulin G 7.05 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 1,005 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 7.55 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 1,106 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 1.06 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 1,200 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.98 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 396 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 1,290 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 9.22 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.82 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 357 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -3: Weight: 80 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1583_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1583_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
